Somatic mutation profile of tumor specimen TCGA-D5-6922-01A (aliquot TCGA-D5-6922-01A-11D-1924-10) from TCGA case TCGA-D5-6922, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.0 years (27,771 days).
Specimen TCGA-D5-6922-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00b86148-08c1-495f-8932-66ee16d909ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6922-10A (Blood Derived Normal), aliquot TCGA-D5-6922-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f4b3559-9354-452e-b62a-bba2db618620

The open-access MAF lists 110 somatic variants for this specimen: 83 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 25, Nonsense Mutation 6, Intron 2, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 40/50 reads (80%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.1409-1G>A p.X470_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | catalogued as rs863225313, CS106547, CS991292, COSV57336165; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DYSF | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs369607332, CM053204, COSV50377641; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 44/76 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.3143G>A p.W1048* | Nonsense Mutation (SNP) | VAF 23/108 reads (21%) | catalogued as COSV52644142; called by muse, mutect2, varscan2
- AC090517.4 | c.1378G>C p.G460R | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99974783; called by muse, mutect2, varscan2
- ACP4 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs752612021, COSV54518621; called by muse, mutect2, varscan2
- ALPP | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV67397900; called by muse, mutect2, varscan2
- ANKRD44 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781422169, COSV56570105; called by muse, mutect2, varscan2
- ARID1A | c.4477C>T p.Q1493* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV61371210, COSV61372378; called by muse, mutect2, varscan2
- ASAP2 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs752933805, COSV55637914; called by muse, mutect2, varscan2
- B3GALT2 | c.403C>G p.H135D | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV66464515; called by muse, mutect2, varscan2
- BRIP1 | c.1859T>G p.M620R | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52007677; called by muse, mutect2, varscan2
- CALD1 | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV62653246; called by muse, mutect2, varscan2
- CASKIN1 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58876464; called by muse, mutect2, varscan2
- CELA2B | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1251576106, COSV65546267; called by muse, mutect2
- COQ3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV54641762; called by muse, mutect2, varscan2
- CORO7 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs759014697, COSV99227888; called by muse, varscan2
- CTNNA2 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM142356, COSV63598951; called by muse, varscan2
- CXCR1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.258); catalogued as rs56030518; called by muse, mutect2, varscan2
- DLEC1 | c.2614C>T p.R872C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs370165845; called by muse, mutect2, varscan2
- DLG2 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54681198; called by muse, mutect2, varscan2
- ECEL1 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs371924008; called by muse, mutect2, varscan2
- ECPAS | c.4989C>A p.S1663R | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as COSV52206439; called by muse, mutect2, varscan2
- EID3 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs751970447, COSV61601123; called by muse, mutect2, varscan2
- FAM120A | c.1433A>G p.N478S | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.969); catalogued as rs923570961, COSV52910237; called by muse, mutect2, varscan2
- FAM124A | c.122C>T p.A41V (on ENST00000322475 / NM_001242312.2; = p.A77V on NM_145019.4) | Missense Mutation (SNP) | VAF 77/112 reads (69%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1237073980, COSV54479844; called by muse, mutect2, varscan2
- FBXL18 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs368029192; called by muse, mutect2, varscan2
- FMNL3 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757430612, COSV53302046; called by mutect2, varscan2
- FMO4 | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63001493, COSV63001879; called by muse, mutect2, varscan2
- FOXD4L5 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1221899275, COSV101072967; called by mutect2, varscan2
- FSIP1 | c.1553C>T p.T518I | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs1247196064, COSV63226700; called by muse, mutect2, varscan2
- GRIN2B | c.4244C>T p.S1415L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs201463390, COSV74206052; called by muse, mutect2, varscan2
- GSE1 | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs991199912, COSV53675734, COSV99495854; called by muse, mutect2, varscan2
- GZMA | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs765136087, COSV57114293; called by muse, mutect2, varscan2
- HCN1 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs1242068538, COSV100302034, COSV57497988; called by muse, mutect2, varscan2
- IFITM5 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs777888777, COSV66888598; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 115/146 reads (79%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1394614053, COSV61176798; called by muse, mutect2, varscan2
- IVL | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV64216195; called by muse, mutect2, varscan2
- LRRIQ3 | c.688T>G p.L230V | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV63043542, COSV63049378; called by muse, mutect2, varscan2
- LTBP2 | c.3305T>C p.V1102A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100000695; called by muse, mutect2, varscan2
- MFN1 | c.969C>G p.I323M | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV54942258; called by muse, mutect2, varscan2
- MLLT1 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1277956766, COSV53133115; called by muse, mutect2, varscan2
- NBEA | c.2462T>A p.V821E | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59819215; called by muse, mutect2, varscan2
- NLGN2 | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs749178079, COSV57209699; called by muse, mutect2, varscan2
- NPBWR2 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs767389109, COSV63899978; called by muse, mutect2, varscan2
- NR0B1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.278); catalogued as CX941934, COSV66764735; called by muse, mutect2, varscan2
- NRIP1 | c.1613C>A p.S538Y | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.742); catalogued as COSV59659933; called by muse, mutect2, varscan2
- NTN3 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53548700; called by muse, mutect2, varscan2
- PIK3R1 | c.1397T>G p.L466* (on ENST00000521381 / NM_181523.3; = p.L196* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99147111; called by muse, mutect2, varscan2
- PYGB | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1454773924, COSV53822477; called by muse, mutect2
- RELCH | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV56891664; called by muse, mutect2, varscan2
- RNASEL | c.338C>G p.S113C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV62377859; called by muse, mutect2, varscan2
- RYR1 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.459); catalogued as rs144845360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.13532C>G p.A4511G (on ENST00000389232; = p.A4512G on NM_001036.6) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101213257; called by muse, mutect2, varscan2
- SLC6A17 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV58996440; called by muse, mutect2, varscan2
- SPATA20 | c.1895T>G p.L632R (on ENST00000356488 / NM_001258372.1; = p.L648R on NM_022827.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV99136306; called by muse, mutect2, varscan2
- SPATA5 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV56783468; called by muse, mutect2, varscan2
- ST6GAL2 | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | PolyPhen possibly damaging (0.599); catalogued as rs776266456, COSV100699515, COSV62415788, COSV62417299; called by muse, mutect2, varscan2
- SYK | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs200167353, COSV65328112; called by muse, mutect2, varscan2
- TASOR2 | c.2524C>G p.L842V | Missense Mutation (SNP) | VAF 76/107 reads (71%) | SIFT tolerated (0.5); PolyPhen benign (0.136); catalogued as COSV60169426; called by muse, mutect2, varscan2
- TBK1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV59158113; called by muse, mutect2, varscan2
- TCF7L2 | c.1462C>T p.R488C (on ENST00000355995 / NM_001367943.1; = p.R465C on NM_030756.5) | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1264066389, COSV53335962, COSV53336193; called by muse, varscan2
- VIP | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as COSV65889572; called by muse, mutect2, varscan2
- VPS13C | c.3986G>A p.R1329Q (on ENST00000644861 / NM_020821.3; = p.R1286Q on NM_017684.5) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs575609391, COSV51421986; called by muse, mutect2, varscan2
- WASF3 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 53/73 reads (73%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs758369538, COSV58963727; called by muse, mutect2, varscan2
- WDR17 | c.3002C>T p.A1001V | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV54582557; called by muse, mutect2, varscan2
- WDR90 | c.2005G>T p.D669Y | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53466926, COSV53474842; called by muse, mutect2, varscan2
- XPO4 | c.2687G>A p.R896Q | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs764304462, COSV55004380; called by muse, mutect2, varscan2
- ZBTB16 | c.1870C>T p.H624Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60099007; called by muse, mutect2, varscan2
- ZBTB20 | c.1600G>A p.G534S (on ENST00000474710 / NM_001164342.2; = p.G461S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61861547, COSV61866513; called by muse, mutect2, varscan2
- ZDHHC19 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs192491896, COSV99579731; called by muse, mutect2, varscan2
- ZIC4 | c.7T>C p.Y3H | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV67173966; called by muse, mutect2, varscan2
- ZMAT2 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.088); catalogued as COSV51227453; called by muse, mutect2, varscan2
- ZNF423 | c.3646G>A p.D1216N (on ENST00000563137 / NM_001379286.1; = p.D1208N on NM_015069.4) | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV99282800; called by muse, mutect2, varscan2
- ZNF689 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV54910007; called by muse, mutect2, varscan2
- ACSL6 | c.1342G>A p.A448T (on ENST00000379240; = p.A473T on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.362); called by muse, mutect2
- CUBN | c.4615G>A p.V1539I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2
- DNAJC7 | c.691_695del p.Q231Ffs*10 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by pindel, varscan2
- LGI4 | c.1544dup p.L516Pfs*7 | Frame Shift Ins (INS) | VAF 43/105 reads (41%) | called by mutect2, pindel, varscan2
- LUC7L | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZC3H13 | c.1909_1912del p.R637Ifs*28 | Frame Shift Del (DEL) | VAF 111/190 reads (58%) | called by pindel, varscan2
- ANK2 | c.5382G>A p.K1794= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100002934; called by muse, mutect2, varscan2
- ASPSCR1 | c.561G>A p.S187= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs774678478, COSV100144947, COSV60730774; called by muse, mutect2, varscan2
- B3GALT2 | c.402C>T p.Y134= | Silent (SNP) | VAF 71/220 reads (32%) | catalogued as COSV66464519; called by muse, mutect2, varscan2
- C9orf50 | c.642G>A p.S214= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV65252140; called by muse, mutect2, varscan2
- CLCN5 | c.462C>T p.A154= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as rs782463692, COSV56586619; called by muse, mutect2, varscan2
- COL18A1 | c.3159G>A p.P1053= (on ENST00000359759 / NM_130444.3; = p.P818= on NM_030582.4) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs770956019, COSV60593205; called by muse, mutect2, varscan2
- DDIT4L | c.510C>T p.L170= | Silent (SNP) | VAF 67/149 reads (45%) | catalogued as COSV56768014; called by muse, mutect2, varscan2
- DENND6B | c.1182G>A p.A394= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs367718224; called by muse, mutect2, varscan2
- FGGY | c.1488C>T p.A496= | Silent (SNP) | VAF 105/252 reads (42%) | catalogued as rs757211105, COSV58044597; called by muse, mutect2, varscan2
- HYAL4 | c.681C>T p.N227= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs745604701, COSV56140225; called by muse, mutect2, varscan2
- IGFBP6 | c.438G>A p.T146= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs200806560, COSV56856948; called by muse, mutect2, varscan2
- MINAR1 | c.1995C>T p.H665= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs757401665, COSV59586147; called by muse, mutect2, varscan2
- MUC5B | c.15867G>A p.P5289= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs778317816, COSV71595109; called by muse, mutect2, varscan2
- MYH6 | c.2364G>A p.T788= | Silent (SNP) | VAF 34/43 reads (79%) | catalogued as rs779838927, COSV62453578; ClinVar: likely benign; called by muse, mutect2, varscan2
- OPRM1 | c.135C>T p.C45= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs199980523, COSV57675141, COSV57687581; called by muse, mutect2, varscan2
- OR2M3 | c.693A>T p.G231= | Silent (SNP) | VAF 63/295 reads (21%) | catalogued as COSV101513483; called by muse, mutect2, varscan2
- OR5F1 | c.60G>A p.T20= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs368825299; called by muse, mutect2, varscan2
- OR5M1 | c.96T>G p.L32= | Silent (SNP) | VAF 21/306 reads (7%) | catalogued as rs960655049, COSV73202301; called by muse, mutect2
- OSMR | c.357C>T p.D119= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs751337172, COSV57091093; called by muse, mutect2, varscan2
- PCDHA9 | c.1125C>T p.I375= | Silent (SNP) | VAF 55/71 reads (77%) | catalogued as COSV65332115; called by muse, mutect2, varscan2
- PRKCSH | c.840C>T p.Y280= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99371755; called by muse, mutect2, varscan2
- ST8SIA6 | c.462C>T p.Y154= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs377694286; called by muse, mutect2, varscan2
- TENM2 | c.750C>T p.P250= (on ENST00000518659 / NM_001122679.2; = p.P59= on NM_001080428.3) | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV69140008; called by muse, mutect2, varscan2
- TNFAIP6 | c.606C>T p.V202= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV54642235; called by muse, mutect2, varscan2
- WIPF3 | c.666G>A p.A222= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as COSV54212395; called by muse, mutect2, varscan2
- CABP1 | c.655-3677G>A | Intron (SNP) | VAF 10/36 reads (28%) | catalogued as rs202143699; called by muse, mutect2, varscan2
- CALCR | c.51+2978C>T | Intron (SNP) | VAF 33/77 reads (43%) | catalogued as rs774519762, COSV64005791, COSV64008954; called by muse, mutect2, varscan2
